Surgical pathology report (de-identified scan), TCGA case TCGA-56-1622, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-1622-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Lymph node (anterior lobular), lymphadenectomy:
Single benign anthracotic lymph node.
- B. Lung (right lower lobe), lobectomy:
Poorly differentiated large cell carcinoma with squamoid features, 3.5 cm in greatest dimension, predominantly endobronchial, but with pulmonary parenchymal invasion (see comment).
Closest inked pleural margin is negative for malignancy.
Bronchus and blood vessels at surgical margin negative for malignancy; negative for lymphovascular invasion.
Non-neoplastic pulmonary parenchyma shows chest wall adhesions; interstitial fibrosis, patchy.
No hilar lymph nodes identified.
- C. Lymph nodes (subcarinal), lymphadenectomy:
Five benign anthracotic lymph nodes.
Adjacent soft tissue with dystrophic calcifications.
- D. Lymph nodes (right hilum), lymphadenectomy:
Two benign anthracotic lymph nodes.
- E. Lymph nodes (right lower peritracheal area), lymphadenectomy:
Five benign anthracotic lymph nodes.
- F. Lung (right middle lobe), wedge biopsy:
Benign pulmonary parenchyma with pleural adhesions.

COMMENTS:

The endobronchial tumor in the right lower lobe (block B2) is stained with a battery of immunohistochemical stains to better categorize the nature of the tumor. The tumor cells are strongly reactive with high molecular weight cytokeratin (SK) and greater than 70% of the tumor cell nuclei are positive with p63. CD56 marks about 5-10% of the tumor cell cytoplasm and cytokeratin 5/6 marks approximately 20-30% of the tumor cells. Cytokeratin 7 and thyroid transcription factor-1 (TTF-1) are negative. These stains support a diagnosis of poorly differentiated squamous carcinoma. The mildly positive CD56 indicates a small component of a neuroendocrine carcinoma. The positive control slides for CK7, TTF-1, CD56, p63, and SK are appropriate. The positive control for CK5/6 is assigned to case [REDACTED]

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Right lower lobe lung cancer.
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Anterior lobar lymph node
- B. Right lower lobe
- C. Right lung subcarinal node
- D. Right lung hilar node
- E. Right lower peritracheal node
- F. Right middle lobe wedge

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container, A, is labeled with the [REDACTED] and interlobar lymph node. The specimen consists of a brown-tan [REDACTED]

[page 2 of 2]
anthracotic nodule consistent with a lymph node measuring 1.0 x 0.5 x 0.2 cm. The specimen is entirely submitted in a single cassette labeled .

B. The second container, B, is labeled with the patient's name, _____ on and right lower lobe. The specimen consists of a lobectomy specimen that measures 15.0 x 15.0 x 4.0 cm and weighs 387 gm. The pleural surface is brown-tan to purple-gray and slightly shaggy. There is a portion of adhered fibromembranous tissue measuring 14.0 x 10.0 cm that is yellow to brown-tan and hemorrhagic. The bronchus has been opened to reveal a gray-tan to red-tan, hemorrhagic mass measuring 3.5 x 3.0 x 2.5 cm that is 0.3 cm from the inked pleural margin and is 3.2 cm from the bronchial margin of resection. Sectioning through the surrounding lung tissue reveals a red-tan, spongy cut surface. There is one possible hilar node identified measuring 0.3 cm. Representative sections were taken for genomic studies and placed in orange cassettes labeled A, B, and C. Also received with the specimen are two cassettes, one green and one yellow, labeled _____. Representative sections are submitted in cassettes _____ as follows: Sections from mass in blocks 1 through 5; sections from bronchial vascular margin block 6; sections from surrounding lung tissue displaying the inked margin of the adhered fibromembranous tissue in blocks 7 and 8; possible hilar node block 9.

C. The third container, C, is labeled with the patient's name _____ and right lung subcarinal node. The specimen consists of five brown-tan anthracotic nodules consistent with lymph nodes measuring from 0.5 to 1.5 cm. The largest is bisected and the specimen is entirely submitted in cassettes _____ as follows: Two probable nodes block 1; two probable nodes block 2; one lymph node, bisected, block 3.

D. The fourth container, D, is labeled with the patient's name, _____ and right lung hilar node. The specimen consists of two brown-tan anthracotic nodules consistent with lymph nodes measuring 0.3 and 0.4 cm in greatest dimension. The specimen is entirely submitted in single cassette _____

E. The fifth container, E, is labeled with the patient's name, _____ and right lower paratracheal node. The specimen consists of five brown-tan anthracotic nodules consistent with lymph nodes measuring from 0.2 to 0.9 cm. The specimen is submitted in two cassettes labeled _____ (lymph nodes are submitted whole).

F. The sixth container, F, is labeled with the patient's name, _____ and right middle lobe wedge. The specimen consists of a wedge resection of lung measuring 4.0 x 2.0 x 0.9 cm, weighing 5 gm. The pleural surface is purple-gray with slight adhesion. The 2.0 mm stable edge has been removed. The subsequent margin has been inked. The specimen is sectioned perpendicular to the inked margin and reveals brown-tan, spongy cut surface. There are no lesions grossly identified. The specimen is entirely submitted in five cassettes labeled _____

Source: NCI Genomic Data Commons file 6769f444-f4ff-4c1d-9b53-dae9b3eee201 (TCGA-56-1622.8B6C2041-DFF4-4CE6-BBD1-683736983803.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).